Gene-level copy-number profile of tumor specimen TCGA-DD-A11A-01A from TCGA case TCGA-DD-A11A, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 67.5 years (24,646 days).
Specimen TCGA-DD-A11A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.fe34dc05-14a2-4b2c-afc7-2665697e5ba9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A11A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/75960c2c-c395-4d36-9605-e36dfc4fe444

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 548; copy number 2: 11,738; copy number 3: 18,275; copy number 4: 17,271; copy number 5: 7,096; copy number 6: 3,753; copy number 7: 664; copy number 8: 451; copy number 9: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A11A-01A-11D-A12Y-01): tumor purity 0.8, ploidy 3.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:141,302,910–141,431,284, 3 genes (within-gene range 0–2): LINC02432, AC097504.1, AC097504.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,130 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,796,014–163,769,691, 185 genes, copy number 8 (broad region; genes not listed).
- chr1:164,921,318–170,532,647, 132 genes, copy number 8 (broad region; genes not listed).
- chr1:211,082,872–216,423,448, 96 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr2:26,847,747–27,446,481, 37 genes, copy number 8 (within-gene range 6–8): DPYSL5, AC013472.1, MAPRE3, MAPRE3-AS1, TMEM214, AGBL5, AGBL5-AS1, AC013472.2, AGBL5-IT1, AC013403.2, OST4, EMILIN1, KHK, CGREF1, ABHD1, PREB, PRR30, TCF23, AC013403.1, SLC5A6, ATRAID, CAD, SLC30A3, DNAJC5G, TRIM54, UCN, MPV17, GTF3C2, GTF3C2-AS1, AC074117.1, EIF2B4, SNX17, ZNF513, PPM1G, FTH1P3, NRBP1, KRTCAP3.
- chr2:27,455,156–27,455,862, 1 gene, copy number 8: AC074117.2.
- chr2:61,527,340–66,573,869, 111 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:1,470,277–33,877,180, 553 genes, copy number 7 (broad region; genes not listed).
- chr8:143,541,648–143,656,418, 15 genes, copy number 9 (within-gene range 5–9): AC067930.9, AC067930.3, RN7SKP175, GSDMD, MROH6, AC067930.4, NAPRT, AC067930.5, AC067930.1, EEF1D, TIGD5, PYCR3, GFUS, AC067930.2, ZNF623.

Autosomal genes at a single copy (total copy number 1): 43. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
